Somatic mutation profile of tumor specimen TCGA-AJ-A3BK-01A (aliquot TCGA-AJ-A3BK-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3BK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 68.3 years (24,943 days).
Specimen TCGA-AJ-A3BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efecc9ec-e20e-4acf-a387-144c03578371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BK-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BK-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59f30b08-f0b2-490f-900a-ae683c9b7a40

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, In Frame Del 2, 3'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, mutect2, varscan2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV100589073; called by muse, mutect2, varscan2
- B4GALT4 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763214004, COSV100785859; called by muse, mutect2, varscan2
- CCDC87 | c.2152G>T p.V718L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as COSV100040231; called by muse, mutect2, varscan2
- CD80 | c.822_824del p.R276del | In Frame Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1560052660; called by mutect2, pindel, varscan2
- CHD9 | c.4278G>T p.W1426C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99529847; called by muse, mutect2
- CLCN5 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100260428; called by muse, mutect2, varscan2
- CLEC14A | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60564115; called by muse, mutect2, varscan2
- CTCF | c.1358-2A>C p.X453_splice | Splice Site (SNP) | VAF 45/161 reads (28%) | catalogued as COSV50467399, COSV99866751; called by muse, mutect2, varscan2
- FAM189A2 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs569881416, COSV99975444; called by muse, mutect2, varscan2
- FMN2 | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100147535, COSV60421399; called by muse, mutect2, varscan2
- GAK | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368206833, COSV100034167; called by muse, mutect2, varscan2
- GCLC | c.804T>G p.Y268* (on ENST00000643939; = p.Y266* on NM_001498.4) | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99988980; called by muse, mutect2, varscan2
- HAVCR1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV100208654; called by muse, mutect2, varscan2
- HIRIP3 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs750398926, COSV99663380; called by muse, mutect2, varscan2
- HMBOX1 | c.699C>T p.G233= | Splice Region (SNP) | VAF 33/56 reads (59%) | catalogued as rs372681580; called by muse, mutect2, varscan2
- IGHG1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1126496; called by muse, mutect2, varscan2
- IGKV1D-17 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs370157163; called by muse, mutect2, varscan2
- ITSN1 | c.4592C>T p.T1531I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101181008; called by muse, mutect2, varscan2
- KMT2C | c.7825C>T p.R2609* | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as COSV51419035; called by muse, mutect2, varscan2
- LRRC27 | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100690003; called by muse, mutect2, varscan2
- MAGEA4 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV52341187, COSV99367752; called by muse, mutect2, varscan2
- MED25 | c.2236C>T p.L746F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1356496852, COSV100458086; called by muse, mutect2, varscan2
- MGAM | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202196208, COSV101527783; called by muse, mutect2, varscan2
- MMAA | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374795215, COSV55579017, COSV55581285; called by muse, mutect2, varscan2
- MOGAT2 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV99549789; called by muse, mutect2
- NEK2 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100878792, COSV65355549; called by muse, mutect2, varscan2
- OLFM3 | c.454G>C p.E152Q (on ENST00000338858 / NM_001288821.1; = p.E132Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as COSV58805324; called by muse, mutect2, varscan2
- OPN5 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200503533, COSV55244335, COSV99790076; called by muse, mutect2, varscan2
- OSBPL6 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV51911886; called by muse, mutect2, varscan2
- POLG | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs754245040, COSV99175115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs146650273; called by pindel, varscan2
- RBM41 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); catalogued as COSV99179847; called by muse, mutect2, varscan2
- SLC39A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs752125791, COSV100135725; called by muse, mutect2, varscan2
- SLC4A7 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.071); catalogued as COSV99840444; called by muse, mutect2, varscan2
- SLCO2B1 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs765284410, COSV99215283; called by muse, mutect2, varscan2
- SMARCA2 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1272801026, COSV100571582; called by muse, mutect2, varscan2
- UNC13C | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs374238210; called by muse, mutect2, varscan2
- VPS72 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as rs1355189756, COSV100614537, COSV63167586; called by muse, mutect2, varscan2
- WSCD2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54578847; called by muse, mutect2, varscan2
- XIRP2 | c.4981A>T p.I1661F (on ENST00000628543; = p.I1836F on NM_152381.6) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99748276; called by muse, mutect2, varscan2
- ZNF385B | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs148361659, COSV61180284; called by muse, mutect2, varscan2
- ZNF471 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV57292009, COSV57293491; called by muse, mutect2, varscan2
- CCDC88A | c.1639_1640del p.E547Kfs*7 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by pindel, varscan2
- HNRNPD | c.357del p.K119Nfs*6 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- PTEN | c.504_512del p.I168_Q171delinsM | In Frame Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- BUB1 | c.543C>T p.N181= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1201408486, COSV100241723; called by muse, mutect2, varscan2
- CADPS2 | c.1440G>A p.V480= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100466437; called by muse, mutect2, varscan2
- CLTB | c.651G>A p.S217= (on ENST00000310418 / NM_007097.5; = p.S199= on NM_001834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs764888931, COSV51258020; called by muse, mutect2
- KAZN | c.561C>T p.S187= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs755553183, COSV100748135; called by muse, mutect2, varscan2
- KIF18B | c.858C>T p.N286= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs765329301, COSV100192664; called by muse, mutect2, varscan2
- PIK3CD | c.1053C>T p.N351= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs776959413, COSV100740588; called by muse, mutect2, varscan2
- RAD50 | c.2307A>G p.E769= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99529794; called by muse, mutect2, varscan2
- SLC4A2 | c.642C>T p.D214= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs774633051, COSV100054787; called by muse, mutect2, varscan2
- SLFN11 | c.2685T>C p.I895= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100391081; called by muse, mutect2, varscan2
- VAX1 | c.420C>T p.S140= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs775686724, COSV53331359; called by muse, mutect2, varscan2
- ERBB4 | c.82+112154G>T | Intron (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99634761; called by muse, mutect2, varscan2
- ITPRIPL1 | c.11-13C>A | Intron (SNP) | VAF 38/72 reads (53%) | catalogued as COSV100742259; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928471 G>A | 3'Flank (SNP) | VAF 33/93 reads (35%) | catalogued as COSV60491490; called by muse, mutect2, varscan2
